Somatic mutation profile of tumor specimen MP2PRT-PARYIG-TMP1-A (aliquot MP2PRT-PARYIG-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARYIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,201 days).
Specimen MP2PRT-PARYIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09e01e45-55a1-4999-a2d0-4f801509c061.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARYIG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARYIG-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65261ddb-b1fe-4b78-b905-98501dc6b611

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2, Frame Shift Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 154/533 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.3476G>A p.R1159Q | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs281875187, CM122549, CM122554, COSV61813999, COSV61814572; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ACP7 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 124/533 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100488603; called by muse, mutect2, varscan2
- GRK1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 183/599 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as rs1466388624; called by muse, mutect2, varscan2
- HAPLN4 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 350/1117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs963005338; called by muse, mutect2, varscan2
- MYC | c.176C>A p.P59Q (on ENST00000377970; = p.P74Q on NM_002467.6) | Missense Mutation (SNP) | VAF 321/1040 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
- OR2C3 | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 72/719 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100825589; called by muse, mutect2, varscan2
- PRDM13 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 57/1482 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs778602675; called by muse, mutect2
- SYT5 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 65/591 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs761426547; called by muse, mutect2, varscan2
- XIRP2 | c.8867G>A p.R2956Q (on ENST00000628543; = p.R3131Q on NM_152381.6) | Missense Mutation (SNP) | VAF 149/539 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs757745970, COSV54685802, COSV54722839; called by muse, mutect2, varscan2
- CNTN1 | c.1598C>A p.A533D | Missense Mutation (SNP) | VAF 142/534 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FSCB | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 56/541 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KNG1 | c.1678T>G p.F560V | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PM20D1 | c.659del p.G220Afs*17 | Frame Shift Del (DEL) | VAF 107/581 reads (18%) | called by mutect2, pindel, varscan2
- SETD2 | c.4628_4629insCCT p.R1543_F1544insL | In Frame Ins (INS) | VAF 48/406 reads (12%) | called by mutect2, pindel*, varscan2
- SLC6A19 | c.1882A>G p.M628V | Missense Mutation (SNP) | VAF 129/602 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC18 | c.5455G>T p.E1819* | Nonsense Mutation (SNP) | VAF 95/248 reads (38%) | called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 63/543 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AHNAK | c.9561C>T p.D3187= | Silent (SNP) | VAF 47/422 reads (11%) | catalogued as rs755094537; called by muse, mutect2, varscan2
- SSTR5 | c.846C>T p.S282= | Silent (SNP) | VAF 123/741 reads (17%) | catalogued as rs759030390, COSV53512546; called by muse, mutect2, varscan2
